Somatic mutation profile of tumor specimen C3L-01246-01 (aliquot CPT0080980009) from CPTAC case C3L-01246, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 62.8 years (22,948 days).
Specimen C3L-01246-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ab59fce-8932-4457-8c28-57b768b24655.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01246-72 (Blood Derived Normal), aliquot CPT0081030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0ed2362-1d9b-4533-94c9-7adc84d775cd

The open-access MAF lists 59 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 11, In Frame Del 1, 3'Flank 1, RNA 1, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 18/174 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.2693G>A p.R898Q | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as rs1291818546; called by muse, mutect2
- CAMK1G | c.888G>C p.Q296H | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV50528966; called by muse, mutect2
- CCDC88B | c.2438C>A p.A813E | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100105289; called by muse, mutect2, varscan2
- CDKN2A | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 75/295 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as CM970251, COSV100446243, COSV58683273, COSV58688196; called by muse, mutect2, varscan2
- CELF2 | c.524C>T p.A175V (on ENST00000416382 / NM_001025077.3; = p.A182V on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV59978719; called by muse, varscan2
- CELSR3 | c.8753G>A p.R2918Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs780586975, COSV50847158; called by muse, mutect2, varscan2
- CLTCL1 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 73/333 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372404195; called by muse, mutect2, varscan2
- DMRTB1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs770956387, COSV65113183; called by muse, mutect2, varscan2
- EPS15L1 | c.507C>A p.D169E | Missense Mutation (SNP) | VAF 19/295 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.162); catalogued as COSV99932995; called by muse, mutect2
- ERCC1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 24/405 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745774178; called by muse, mutect2
- FRAS1 | c.287A>C p.H96P | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.53); catalogued as COSV53596240; called by muse, mutect2
- LILRA4 | c.781G>C p.D261H | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.824); catalogued as COSV52490004; called by muse, mutect2
- MUC16 | c.26537C>T p.S8846L | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as rs144604762, COSV67476106; called by muse, mutect2, varscan2
- PLAT | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 19/305 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV54277633; called by muse, mutect2
- RAD51AP2 | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.391); catalogued as COSV67588173; called by muse, mutect2, varscan2
- RTL6 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100373868; called by muse, mutect2, varscan2
- SCN1A | c.1928G>A p.S643N | Missense Mutation (SNP) | VAF 29/323 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as rs369178649, COSV100322910; called by muse, mutect2
- TP53 | c.647_648dup p.V217Wfs*31 | Frame Shift Ins (INS) | VAF 236/631 reads (37%) | catalogued as COSV53840613; called by mutect2, pindel, varscan2
- WIZ | c.2467G>C p.G823R (on ENST00000673675 / NM_001371589.1; = p.G86R on NM_021241.3) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV54609300; called by muse, mutect2
- ZNF836 | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.591); catalogued as rs924209215, COSV59083186; called by muse, mutect2
- ZSCAN10 | c.1784C>T p.A595V (on ENST00000252463; = p.A650V on NM_032805.3) | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs748853111, COSV52967696; called by muse, mutect2, varscan2
- AOX1 | c.4014C>G p.I1338M | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2
- BNIPL | c.724A>C p.M242L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- C18orf63 | c.1429C>G p.Q477E | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- C8A | c.1264C>G p.R422G | Missense Mutation (SNP) | VAF 54/419 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CDS2 | c.463A>T p.R155* | Nonsense Mutation (SNP) | VAF 17/372 reads (5%) | called by muse, mutect2
- CNBD1 | c.404T>G p.L135R | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ESPL1 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EVPL | c.3761C>T p.T1254I | Missense Mutation (SNP) | VAF 109/246 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM83C | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KRTAP9-7 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 35/609 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.295); called by muse, mutect2
- LRATD2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 108/339 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRP6 | c.2692G>T p.G898W | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LVRN | c.422C>T p.T141I | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- P2RY13 | c.432G>C p.K144N | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RP1 | c.2399A>C p.K800T | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.192); called by muse, mutect2
- SNAP91 | c.775A>G p.I259V | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.098); called by muse, mutect2
- SOBP | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TAF15 | c.667G>T p.D223Y (on ENST00000605844 / NM_139215.3; = p.D220Y on NM_003487.4) | Missense Mutation (SNP) | VAF 123/484 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TATDN1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, varscan2
- TRIM23 | c.1568_1570del p.V523del | In Frame Del (DEL) | VAF 10/130 reads (8%) | called by mutect2, pindel
- XPO1 | c.79T>G p.L27V | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.181); called by muse, mutect2
- ZNF469 | c.9691G>C p.E3231Q (on ENST00000437464; = p.E3259Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- AGXT2 | c.543C>T p.A181= | Silent (SNP) | VAF 33/279 reads (12%) | called by muse, mutect2, varscan2
- BCR | c.1668C>T p.I556= | Silent (SNP) | VAF 21/222 reads (9%) | called by muse, mutect2, varscan2
- CBX7 | c.171C>T p.Y57= | Silent (SNP) | VAF 11/137 reads (8%) | catalogued as rs1434832542; called by muse, mutect2
- CHRM3 | c.1389G>T p.L463= | Silent (SNP) | VAF 20/229 reads (9%) | catalogued as rs200635440; called by muse, mutect2
- CRACD | c.2658G>A p.A886= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as rs1317053467, COSV99949959; called by muse, mutect2
- CSMD3 | c.3447C>T p.L1149= (on ENST00000297405 / NM_001363185.1; = p.L1045= on NM_052900.3) | Silent (SNP) | VAF 28/566 reads (5%) | catalogued as COSV52122270; called by muse, mutect2
- CYP2W1 | c.12G>C p.L4= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- HUWE1 | c.1005C>G p.V335= | Silent (SNP) | VAF 23/200 reads (12%) | catalogued as COSV53358373, COSV99473651; called by muse, mutect2, varscan2
- MYOF | c.4632A>G p.E1544= | Silent (SNP) | VAF 18/268 reads (7%) | called by muse, mutect2
- PSG2 | c.117A>G p.E39= | Silent (SNP) | VAF 28/211 reads (13%) | called by mutect2, varscan2
- RAD21L1 | c.1411T>C p.L471= | Silent (SNP) | VAF 9/135 reads (7%) | catalogued as rs1323680037; called by muse, mutect2
- C11orf96 | chr11:43943787 G>T | 3'Flank (SNP) | VAF 18/174 reads (10%) | catalogued as rs1011280384; called by muse, mutect2
- CLN3 | c.222+691T>A | Intron (SNP) | VAF 22/178 reads (12%) | called by muse, varscan2
- PABPC1L | c.*43C>T | 3'UTR (SNP) | VAF 32/306 reads (10%) | called by muse, mutect2, varscan2
- SNORD114-26 | n.2G>T | RNA (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
